Gene-level copy-number profile of tumor specimen TCGA-LN-A7HX-01A from TCGA case TCGA-LN-A7HX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.6 years (26,517 days).
Specimen TCGA-LN-A7HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.9531cbd7-8a33-4b9f-80dd-68943d509ffe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A7HX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b48f9187-2286-454b-8621-e96f757feb15

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 597; copy number 2: 5,404; copy number 3: 16,266; copy number 4: 18,711; copy number 5: 9,382; copy number 6: 1,987; copy number 7: 5,062; copy number 8: 1,659; copy number 9: 461; copy number 11: 52; copy number 12: 35; copy number 13: 8; copy number 14: 23; copy number 20: 2; copy number 22: 4; copy number 24: 11; copy number 30: 15; copy number 31: 95; copy number 40: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A7HX-01A-11D-A33D-01): tumor purity 0.58, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 736 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:98,987,387–99,216,266, 2 genes, copy number 9: U7, ACTG1P13.
- chr4:48,341,529–49,062,081, 12 genes, copy number 14: SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:89,111,533–91,601,913, 17 genes, copy number 11–14 (within-gene range 3–14): TIGD2, AC104785.1, RNU6-907P, GPRIN3, AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1, CCSER1, RN7SKP248, AC093729.1, TMSB4XP8.
- chr8:97,132,835–103,501,895, 163 genes, copy number 9 (broad region; genes not listed).
- chr8:103,559,099–103,568,978, 2 genes, copy number 9: PTMAP15, AC007751.1.
- chr8:121,612,116–126,558,478, 100 genes, copy number 9 (broad region; genes not listed).
- chr8:126,582,631–126,583,006, 1 gene, copy number 9: AC083923.1.
- chr11:68,683,779–75,206,549, 227 genes, copy number 9–31 (within-gene range 8–31) (broad region; genes not listed).
- chr11:92,336,032–93,812,378, 46 genes, copy number 11 (within-gene range 8–11): NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2.
- chr13:52,012,398–53,939,960, 38 genes, copy number 9–20: ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD, MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1, LINC00558.
- chr13:73,036,401–74,259,976, 14 genes, copy number 30: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402.
- chr13:74,289,100–74,289,214, 1 gene, copy number 30: RNY1P5.
- chr13:107,868,823–107,933,503, 1 gene, copy number 13 (within-gene range 8–13): AL359436.1.
- chr13:108,207,439–108,481,817, 7 genes, copy number 13: LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1.
- chr13:111,865,136–113,641,473, 45 genes, copy number 24–40: LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1.
- chr19:56,387,412–57,482,996, 60 genes, copy number 9: AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835, AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1, ZNF548, AC003002.3, AC003002.2, ZNF17, ZNF749, AC004076.1, AC004076.2, VN1R1, VN1R107P, ZNF772, AC003005.2.

Autosomal genes at a single copy (total copy number 1): 597. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
